Somatic mutation profile of tumor specimen TARGET-10-PAPIIX-09A (aliquot TARGET-10-PAPIIX-09A-01D) from TARGET case TARGET-10-PAPIIX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,337 days).
Specimen TARGET-10-PAPIIX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 315c26b6-484e-4c1f-82d0-c527c3f0b1c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPIIX-10A (Blood Derived Normal), aliquot TARGET-10-PAPIIX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ace47b04-2501-410e-833c-f2f82eefdf07

The open-access MAF lists 34 somatic variants for this specimen: 17 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 12, 3'UTR 2, Intron 1, 5'UTR 1, Frame Shift Ins 1, Frame Shift Del 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM13C | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs534813877, COSV53252651, COSV99513189; called by muse, mutect2, varscan2
- FSIP2 | c.10249G>C p.E3417Q | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.617); catalogued as COSV58099337; called by muse, mutect2
- GRID2IP | c.3562G>A p.E1188K | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1214271962, COSV101474838; called by muse, mutect2, varscan2
- KIF1C | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs1320673365; called by muse, mutect2, varscan2
- NSD2 | c.3373G>A p.D1125N | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56386535; called by muse, mutect2, varscan2
- OR2H1 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as rs754893654, COSV101009862, COSV65810302; called by muse, mutect2, varscan2
- OTOF | c.4924G>A p.V1642I (on ENST00000272371 / NM_194248.3; = p.V875I on NM_004802.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs146552124; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RRP1B | c.271+1G>A p.X91_splice | Splice Site (SNP) | VAF 6/66 reads (9%) | catalogued as rs752847304; called by mutect2, varscan2
- ZNF197 | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV100482240; called by muse, mutect2, varscan2
- ABCC4 | c.633C>G p.F211L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2
- ADAMTS9 | c.1093A>G p.K365E | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- IGHV3-21 | chr14:106235056 del ACTGTGTCTCTCG | Missense Mutation (DEL) | VAF 19/22 reads (86%) | called by mutect2, varscan2*
- PDE11A | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2
- SLC17A6 | c.1679del p.K560Rfs*33 | Frame Shift Del (DEL) | VAF 29/81 reads (36%) | called by mutect2, pindel, varscan2
- VWA5B1 | c.2873A>G p.N958S (on ENST00000375079; = p.N959S on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- XPNPEP1 | c.1469T>C p.V490A | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGAP21 | c.3033C>T p.L1011= | Silent (SNP) | VAF 4/89 reads (4%) | called by muse, mutect2
- FASTKD2 | c.1128G>T p.G376= | Silent (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- FER1L6 | c.4074C>T p.I1358= | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- H2BC12 | c.9A>G p.E3= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs764224999, COSV63616679; called by muse, mutect2
- HCRTR2 | c.597C>T p.G199= | Silent (SNP) | VAF 31/52 reads (60%) | called by muse, mutect2, varscan2
- IGHV3-13 | chr14:106129537 GTGT>C | Silent (DEL) | VAF 24/28 reads (86%) | called by pindel, varscan2*
- LY6G5C | c.351G>A p.K117= (on ENST00000375863; = p.K42= on NM_025262.3) | Silent (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- NCF2 | c.642C>T p.F214= | Silent (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- PRICKLE4 | c.630G>C p.S210= (on ENST00000359201; = p.S250= on NM_013397.6) | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs1245620984; called by muse, mutect2, varscan2
- UNC5A | c.351C>T p.F117= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs1363407886; called by muse, mutect2
- ZBBX | c.291G>A p.V97= | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- ZNF516 | c.300G>A p.A100= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs1160441386, COSV101487388; called by muse, mutect2, varscan2
- DUSP13 | c.*447G>A | 3'UTR (SNP) | VAF 12/104 reads (12%) | catalogued as rs140630872; called by muse, mutect2, varscan2
- IGSF9B | chr11:133956789 C>T | 5'Flank (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- OTOF | c.2215-145C>T | Intron (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- SLC1A1 | c.*79G>A | 3'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- TANK | c.-43C>T | 5'UTR (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
